Surgical pathology report (de-identified scan), TCGA case TCGA-27-1832, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta, specimen TCGA-27-1832-01A (Primary Tumor).

Ref. Number

TCGA-27-1832

Gender

Female

Birth date

Tumor site

Right fronto-temporal

Histological diagnosis

Glioblastoma multiforme

Note: for

only

Source: NCI Genomic Data Commons file a422167c-f7dc-4a45-9993-d10d3e8ac684 (TCGA-27-1832.535D412F-ED27-467A-B373-8E26E940C07B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).